Gene-level copy-number profile of tumor specimen HCM-SANG-0297-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1a1a0eb-cf9e-40ab-af88-d6b3c8b8a4eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0297-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/af56fae6-1e87-434b-b9fc-3b35b21fe8c2

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 463; copy number 1: 32,332; copy number 2: 21,628; copy number 3: 3,335; copy number 4: 601; copy number 5: 247; copy number 6: 3; copy number 7: 143; copy number 9: 86; copy number 10: 66.

Homozygous deletions (total copy number 0; autosomes only): 463 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,536,647–2,841,098, 5 genes (within-gene range 0–1): FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:54,657,918–66,431,521, 134 genes (broad region; genes not listed).
- chr4:132,435,802–132,678,503, 3 genes: AC114741.1, LINC01256, AARS1P1.
- chr4:134,026,665–134,327,977, 1 gene (within-gene range 0–1): AC015631.1.
- chr4:134,327,063–136,553,739, 20 genes: PES1P1, LINC02462, AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, KRT18P54, TARS2P1, AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3, AC093875.1.
- chr4:160,521,829–160,818,869, 3 genes: AC093853.1, LINC02477, RPS14P7.
- chr4:162,022,733–162,047,567, 1 gene (within-gene range 0–1): AC023136.1.
- chr4:182,143,987–182,803,024, 1 gene (within-gene range 0–1): TENM3.
- chr4:182,548,659–185,020,804, 61 genes (broad region; genes not listed).
- chr14:26,443,090–26,598,033, 2 genes: NOVA1, AL079343.1.
- chr20:14,352,320–14,352,425, 1 gene (within-gene range 0–1): RNU6-228P.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–1): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:7,744,962–10,397,778, 62 genes (broad region; genes not listed).
- chr21:16,094,415–16,121,644, 2 genes (within-gene range 0–1): VDAC2P1, RPS26P5.
- chr21:16,862,875–22,420,819, 63 genes (broad region; genes not listed).
- chr21:22,882,582–22,884,000, 1 gene: AP000949.1.
- chr22:15,572,089–17,132,104, 71 genes (broad region; genes not listed).
- chr22:18,501,794–18,757,906, 15 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.
- chr22:48,448,890–48,451,217, 1 gene: Z82249.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,481 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–944,581, 5 genes, copy number 3 (within-gene range 2–3): AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11.
- chr1:960,584–1,074,306, 13 genes, copy number 3: KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223.
- chr1:1,137,017–1,311,677, 19 genes, copy number 3–4 (within-gene range 2–4): LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1.
- chr1:1,324,756–1,361,777, 5 genes, copy number 4: CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr4:82,352,498–89,954,629, 134 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 3 (broad region; genes not listed).
- chr5:63,022,919–64,486,615, 6 genes, copy number 3: AC113420.1, AC025445.1, HTR1A, AC122707.1, RNF180, AC091862.1.
- chr5:101,976,296–103,120,138, 14 genes, copy number 3: AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1.
- chr6:47,231,532–48,214,794, 16 genes, copy number 4–9: TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, HNRNPA3P4, RBMXP1.
- chr6:50,818,723–52,087,613, 11 genes, copy number 3: TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P.
- chr7:37,032–1,747,954, 52 genes, copy number 3–4: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:49,850,421–57,777,521, 179 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:73,567,537–80,226,181, 153 genes, copy number 3–4 (broad region; genes not listed).
- chr7:80,742,538–81,770,438, 10 genes, copy number 4: SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:86,643,914–88,226,993, 23 genes, copy number 4 (within-gene range 2–4): GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1.
- chr7:89,882,353–98,870,771, 153 genes, copy number 4 (broad region; genes not listed).
- chr8:142,111,414–144,529,132, 143 genes, copy number 3 (broad region; genes not listed).
- chr10:132,036,336–133,431,318, 44 genes, copy number 3: JAKMIP3, AL512622.1, DPYSL4, STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P.
- chr11:86,649–626,078, 49 genes, copy number 3: OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9, RN7SL838P, PTDSS2, AC138230.1, RNH1, AC137894.1, HRAS, LRRC56, LMNTD2, LMNTD2-AS1, RASSF7, MIR210HG, MIR210, PHRF1, IRF7, CDHR5.
- chr11:63,137,867–63,369,718, 1 gene, copy number 4 (within-gene range 1–4): SLC22A10.
- chr11:63,237,957–63,266,256, 3 genes, copy number 4: AP001880.2, CCND2P1, AP001880.1.
- chr11:67,583,742–67,784,229, 17 genes, copy number 10: GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4.
- chr11:68,980,021–109,823,893, 788 genes, copy number 3–10 (broad region; genes not listed).
- chr11:114,343,052–114,454,123, 6 genes, copy number 6–10 (within-gene range 1–10): AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2.
- chr11:117,427,772–119,381,711, 94 genes, copy number 5–9 (broad region; genes not listed).
- chr11:119,372,706–119,381,613, 1 gene, copy number 5: AP003396.3.
- chr12:132,169,823–132,585,188, 21 genes, copy number 3: AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763.
- chr16:8,508,069–9,518,325, 27 genes, copy number 3: AC074052.1, AC074052.2, TMEM114, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195.
- chr16:19,701,937–19,886,167, 6 genes, copy number 3 (within-gene range 1–3): KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B.
- chr16:24,256,335–32,265,514, 373 genes, copy number 3 (broad region; genes not listed).
- chr16:33,345,182–34,013,830, 32 genes, copy number 3: AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3, AC142384.1, BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2.
- chr17:69,961,568–73,092,712, 32 genes, copy number 3–5: LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1.
- chr18:45,034–14,378,757, 335 genes, copy number 3–4 (broad region; genes not listed).
- chr18:20,946,906–23,672,748, 61 genes, copy number 3–4 (broad region; genes not listed).
- chr19:397,589–1,885,496, 106 genes, copy number 3 (broad region; genes not listed).
- chr20:30,214,765–64,327,972, 870 genes, copy number 3–4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
